Somatic mutation profile of tumor specimen TCGA-D7-A74A-01A (aliquot TCGA-D7-A74A-01A-11D-A32N-08) from TCGA case TCGA-D7-A74A, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 61.4 years (22,435 days).
Specimen TCGA-D7-A74A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4389a900-c0e7-4627-b31b-80ba1a43a4ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-A74A-10A (Blood Derived Normal), aliquot TCGA-D7-A74A-10A-21D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/715cd8e0-024f-483c-b7c7-ff91e42180e8

The open-access MAF lists 156 somatic variants for this specimen: 113 protein-altering or splice-affecting, 39 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 39, Nonsense Mutation 7, Splice Site 3, Splice Region 2, Frame Shift Del 2, In Frame Del 2, Intron 2, 5'Flank 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 142/211 reads (67%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.10347+1G>A p.X3449_splice | Splice Site (SNP) | VAF 20/77 reads (26%) | catalogued as rs111436401, CS157285; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- A1BG | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.104); catalogued as COSV99568313; called by muse, mutect2, varscan2
- AFAP1L1 | c.528G>C p.K176N | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99695835; called by muse, mutect2, varscan2
- AMFR | c.1768C>T p.L590F | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1383383176, COSV99315814; called by muse, varscan2
- AMFR | c.1708C>T p.R570C | Missense Mutation (SNP) | VAF 70/82 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1419932705, COSV99315815; called by muse, varscan2
- ANOS1 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs1205666735, COSV99390791; called by muse, mutect2, varscan2
- ARFGEF3 | c.3612G>A p.M1204I | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV99293194; called by muse, mutect2, varscan2
- ASRGL1 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.516); catalogued as COSV100077817; called by muse, mutect2, varscan2
- ATF3 | c.474G>C p.Q158H | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as COSV99674526; called by muse, mutect2, varscan2
- ATP8B4 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as rs370938976, COSV52711717; called by muse, mutect2, varscan2
- B2M | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 55/161 reads (34%) | catalogued as COSV62563605; called by muse, varscan2
- BMPR1A | c.1315G>T p.E439* | Nonsense Mutation (SNP) | VAF 187/204 reads (92%) | catalogued as COSV100923461; called by muse, mutect2, varscan2
- CALCRL | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs773778926, COSV66474981, COSV66475097; called by muse, mutect2, varscan2
- CARD11 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.172); catalogued as rs766268425, COSV62716853, COSV62719430, COSV62719971; called by muse, mutect2, varscan2
- CCDC110 | c.11-1G>C p.X4_splice | Splice Site (SNP) | VAF 64/157 reads (41%) | catalogued as COSV100293888, COSV56871787; called by muse, mutect2, varscan2
- CCT2 | c.380T>C p.I127T | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs1322642358, COSV100167588; called by muse, mutect2, varscan2
- CDH26 | c.1474G>C p.D492H | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99722263; called by muse, mutect2, varscan2
- CFAP58 | c.1429dup p.I477Nfs*3 | Frame Shift Ins (INS) | VAF 42/220 reads (19%) | catalogued as rs761844995; called by mutect2, varscan2
- CLECL1 | c.409A>G p.K137E | Missense Mutation (SNP) | VAF 35/216 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV100590080; called by muse, mutect2, varscan2
- COL11A1 | c.2261G>T p.G754V | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100616110; called by muse, mutect2, varscan2
- COL3A1 | c.2186G>C p.G729A | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM1412593, COSV100482879; called by muse, mutect2, varscan2
- CSMD3 | c.5666_5668del p.R1889del (on ENST00000297405 / NM_001363185.1; = p.R1785del on NM_052900.3) | In Frame Del (DEL) | VAF 30/198 reads (15%) | catalogued as rs764367027; called by pindel, varscan2
- CSRNP3 | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 114/430 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100085585; called by muse, mutect2, varscan2
- CYP20A1 | c.1349C>T p.S450L | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV100619038; called by muse, mutect2, varscan2
- DIDO1 | c.2334G>C p.V778= | Splice Region (SNP) | VAF 61/281 reads (22%) | catalogued as COSV56613697, COSV99825570; called by muse, mutect2, varscan2
- E2F8 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51462396; called by muse, mutect2, varscan2
- EFR3A | c.1169G>A p.G390E | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV54460414; called by muse, mutect2, varscan2
- EIF2AK3 | c.1552C>G p.L518V | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as COSV100303671; called by muse, mutect2, varscan2
- EIF3E | c.1282C>T p.Q428* | Nonsense Mutation (SNP) | VAF 46/214 reads (21%) | catalogued as COSV55201129; called by muse, mutect2, varscan2
- EN1 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1385564931, COSV99727144; called by muse, mutect2, varscan2
- EPO | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs944280848, COSV53162074; called by muse, mutect2, varscan2
- FAT4 | c.8299G>A p.D2767N | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58685209; called by muse, mutect2, varscan2
- FLG | c.10538C>T p.A3513V | Missense Mutation (SNP) | VAF 141/483 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs143278829, COSV64243057; called by muse, mutect2, varscan2
- FREM1 | c.4319G>T p.G1440V | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101084283; called by muse, mutect2, varscan2
- GABRA3 | c.1250C>A p.S417Y | Missense Mutation (SNP) | VAF 314/350 reads (90%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV64799165; called by mutect2, varscan2
- GOLGA4 | c.4253C>G p.S1418C | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100728822, COSV62714115; called by muse, mutect2, varscan2
- GPC6 | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs376951709, COSV65516774; called by muse, mutect2, varscan2
- HDLBP | c.3439G>A p.G1147S | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100190364; called by muse, mutect2, varscan2
- IKZF1 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs144637662, COSV58787868; called by muse, mutect2, varscan2
- IL1RAPL1 | c.126A>C p.Q42H | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100146765; called by muse, mutect2, varscan2
- IMPDH1 | c.292G>A p.E98K (on ENST00000470772 / NM_001142573.2; = p.E183K on NM_000883.4) | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV100118651; called by muse, mutect2, varscan2
- IPO4 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1284744847, COSV99937935; called by muse, mutect2, varscan2
- KANK4 | c.2886T>G p.A962= | Splice Region (SNP) | VAF 33/65 reads (51%) | catalogued as rs758452262, COSV100443165; called by muse, mutect2, varscan2
- KCNA1 | c.1411G>T p.V471F | Missense Mutation (SNP) | VAF 263/391 reads (67%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs780167432, COSV101230206, COSV66838093; called by muse, mutect2, varscan2
- KIR3DL1 | c.1234A>T p.T412S | Missense Mutation (SNP) | VAF 155/607 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV100373006; called by muse, mutect2, varscan2
- KRT13 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); catalogued as rs781291691, COSV55838986; called by muse, mutect2, varscan2
- LANCL2 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775868537, COSV99634728; called by muse, mutect2, varscan2
- LIPI | c.1256C>G p.S419* | Nonsense Mutation (SNP) | VAF 22/111 reads (20%) | catalogued as COSV100753623; called by muse, mutect2, varscan2
- LPP | c.1007G>C p.G336A | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs754338664, COSV100446805; called by muse, mutect2, varscan2
- MIA3 | c.881G>A p.R294K | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.6); catalogued as COSV100719408; called by muse, mutect2, varscan2
- MPI | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV100086283; called by muse, mutect2, varscan2
- MPP4 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs371295320; called by muse, mutect2, varscan2
- MUC3A | c.7634C>G p.S2545C | Missense Mutation (SNP) | VAF 55/408 reads (13%) | SIFT deleterious, low confidence (0.02); catalogued as COSV60220266; called by muse, mutect2
- MYG1 | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV99266916; called by muse, varscan2
- MYG1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs1431999643, COSV99266918; called by muse, varscan2
- MYO3B | c.3516A>T p.E1172D | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV100509968; called by muse, mutect2, varscan2
- MYRF | c.1745C>T p.S582L (on ENST00000278836 / NM_001127392.3; = p.S573L on NM_013279.4) | Missense Mutation (SNP) | VAF 42/48 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as rs1370128333, COSV53893965, COSV99606932; called by muse, mutect2, varscan2
- NAALADL1 | c.1285_1287del p.E429del | In Frame Del (DEL) | VAF 59/166 reads (36%) | catalogued as rs764129098; called by mutect2, pindel, varscan2
- NCF4 | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367876433; called by muse, mutect2, varscan2
- NEB | c.9154C>T p.R3052W | Missense Mutation (SNP) | VAF 134/462 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs750990726, COSV51471329; called by muse, mutect2, varscan2
- NEDD9 | c.2069C>G p.S690C | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs1189689126, COSV101060827; called by muse, mutect2, varscan2
- NIN | c.2338G>C p.E780Q | Missense Mutation (SNP) | VAF 109/321 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1223722917, COSV99813083; called by muse, mutect2, varscan2
- NOTCH4 | c.5614G>A p.G1872R | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs8192582, COSV100900629; called by muse, mutect2, varscan2
- NPTX2 | c.1240G>A p.G414R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766600008, COSV99674841; called by muse, mutect2, varscan2
- NUCB1 | c.543G>A p.M181I | Missense Mutation (SNP) | VAF 22/231 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as COSV99617829; called by muse, mutect2
- NXPH1 | c.488T>C p.V163A | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV101339668; called by muse, mutect2, varscan2
- OR5H14 | c.529T>G p.F177V | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV101454151; called by muse, mutect2, varscan2
- PANK1 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV100285597; called by muse, mutect2
- PHF20 | c.2480C>T p.P827L | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.849); catalogued as rs770493098, COSV100926571; called by muse, mutect2, varscan2
- PKDREJ | c.1963C>G p.L655V | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV99478735; called by muse, mutect2, varscan2
- POLR1C | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 60/237 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.356); catalogued as COSV99540790; called by muse, mutect2, varscan2
- POLR1G | c.244G>T p.V82F | Missense Mutation (SNP) | VAF 67/254 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100338079; called by muse, mutect2, varscan2
- POLR1G | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV99185267; called by muse, mutect2, varscan2
- POLR1G | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.406); catalogued as COSV99185268; called by muse, mutect2, varscan2
- PPAT | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as COSV99947197; called by muse, mutect2, varscan2
- PPP1R13B | c.2155G>A p.G719R | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775061683, COSV99158501; called by muse, mutect2, varscan2
- PYCR2 | c.315G>C p.E105D | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100661505; called by muse, mutect2, varscan2
- PYROXD2 | c.345C>G p.N115K | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100995951, COSV65331239; called by muse, mutect2, varscan2
- RAB5A | c.368G>A p.S123N | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as COSV99810923; called by muse, mutect2, varscan2
- REV3L | c.5959G>A p.V1987I | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV100725123; called by muse, mutect2, varscan2
- RIMS1 | c.4340G>A p.R1447K | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1234450205, COSV99325979; called by muse, mutect2, varscan2
- RUSC1 | c.2029C>T p.Q677* (on ENST00000368352 / NM_001105203.2; = p.Q208* on NM_014328.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 65/195 reads (33%) | catalogued as COSV99429706; called by muse, mutect2, varscan2
- SERINC4 | c.1502T>G p.L501W | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.237); catalogued as COSV99988380; called by muse, mutect2, varscan2
- SET | c.526G>A p.G176R (on ENST00000372692 / NM_001374326.1; = p.G163R on NM_003011.4) | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV100433062; called by muse, mutect2, varscan2
- SFMBT2 | c.1538T>A p.F513Y | Missense Mutation (SNP) | VAF 106/154 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV100738837; called by muse, mutect2, varscan2
- SIPA1 | c.2575C>T p.L859F | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV100425808; called by muse, mutect2, varscan2
- SLC12A5 | c.2638C>T p.R880C (on ENST00000454036 / NM_001134771.2; = p.R857C on NM_020708.5) | Missense Mutation (SNP) | VAF 57/262 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs764947617, COSV99715855; called by muse, mutect2, varscan2
- SLC28A1 | c.1876G>A p.V626I | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs529135098, COSV99722898; called by muse, mutect2, varscan2
- SLITRK2 | c.1432C>G p.L478V | Missense Mutation (SNP) | VAF 143/460 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100157636; called by muse, mutect2, varscan2
- SLITRK5 | c.2056G>C p.V686L | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs754772123, COSV100280644, COSV61522407; called by muse, mutect2, varscan2
- SMAD3 | c.723C>G p.N241K | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs144667334, COSV100528932; called by muse, mutect2, varscan2
- SPATA20 | c.2042G>A p.R681H (on ENST00000356488 / NM_001258372.1; = p.R697H on NM_022827.4) | Missense Mutation (SNP) | VAF 71/230 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as rs766371817, COSV50070700; called by muse, mutect2, varscan2
- STAT5A | c.1092G>C p.M364I | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV100604555; called by muse, mutect2, varscan2
- SYT6 | c.1460G>A p.R487Q (on ENST00000610222 / NM_001366225.1; = p.R402Q on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs181310527; called by muse, mutect2, varscan2
- TBC1D16 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as rs753753321, COSV100187970; called by muse, varscan2
- TCF4 | c.1233G>T p.M411I | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs774269559, COSV100610082; called by muse, mutect2, varscan2
- TCTN2 | c.1294G>C p.E432Q | Missense Mutation (SNP) | VAF 57/319 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV100315185; called by muse, mutect2, varscan2
- TENM4 | c.5323G>A p.G1775S | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs575393534, COSV99573507; called by muse, mutect2, varscan2
- THEMIS2 | c.1305T>A p.S435R | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as COSV100197977; called by muse, mutect2, varscan2
- TPM2 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 76/90 reads (84%) | SIFT tolerated (0.19); PolyPhen benign (0.15); catalogued as rs778874374, COSV100253183; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1213G>C p.E405Q | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.9); PolyPhen benign (0.421); catalogued as COSV99161037; called by muse, mutect2, varscan2
- TRIM6 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs771784014, COSV53480200; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.2271G>C p.Q757H | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as COSV100708999; called by muse, mutect2, varscan2
- TROAP | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 92/125 reads (74%) | catalogued as rs1039725596, COSV99226802; called by muse, mutect2, varscan2
- TRPC7 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 38/130 reads (29%) | catalogued as COSV100725663; called by muse, mutect2, varscan2
- TRRAP | c.5020G>C p.E1674Q (on ENST00000359863 / NM_001244580.1; = p.E1656Q on NM_003496.3) | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.446); catalogued as COSV100722367, COSV99052843; called by muse, mutect2, varscan2
- TSPAN31 | c.313-1G>C p.X105_splice | Splice Site (SNP) | VAF 25/185 reads (14%) | catalogued as COSV99222948; called by muse, mutect2, varscan2
- UBR4 | c.11015G>C p.G3672A | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100920699; called by muse, mutect2, varscan2
- USP21 | c.1570C>T p.R524W | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99237338; called by muse, mutect2, varscan2
- XIRP1 | c.4397G>C p.R1466T | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as COSV100453556, COSV61138834, COSV61139556; called by muse, mutect2, varscan2
- CCNC | c.549del p.Y184Tfs*13 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | called by mutect2, pindel, varscan2
- KCNJ16 | c.153del p.F51Lfs*25 | Frame Shift Del (DEL) | VAF 70/177 reads (40%) | called by mutect2, pindel, varscan2
- ALG12 | c.903C>G p.L301= | Silent (SNP) | VAF 42/94 reads (45%) | catalogued as COSV58207911; called by muse, mutect2
- ANKS4B | c.1186C>T p.L396= | Silent (SNP) | VAF 52/134 reads (39%) | catalogued as COSV100289793; called by muse, mutect2, varscan2
- B3GALT5 | c.822C>T p.S274= | Silent (SNP) | VAF 47/131 reads (36%) | catalogued as rs372655965; called by muse, mutect2, varscan2
- BUD13 | c.24C>G p.S8= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99496413; called by muse, mutect2, varscan2
- CADM2 | c.1086G>A p.Q362= (on ENST00000407528 / NM_001167674.2; = p.Q364= on NM_153184.4) | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as COSV67392631; called by muse, mutect2, varscan2
- CCZ1 | c.624C>T p.S208= | Silent (SNP) | VAF 25/138 reads (18%) | catalogued as rs1371974344, COSV100382784; called by muse, mutect2, varscan2
- CHKB | c.516G>A p.A172= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs200220080; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL12A1 | c.1134C>T p.H378= | Silent (SNP) | VAF 71/161 reads (44%) | catalogued as rs376523503; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBXL7 | c.1092C>T p.T364= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs1459824630, COSV61649639; called by muse, mutect2, varscan2
- FMNL1 | c.2922C>T p.F974= | Silent (SNP) | VAF 55/213 reads (26%) | catalogued as rs1200274193, COSV100056417; called by muse, mutect2, varscan2
- GSDMC | c.216C>T p.V72= | Silent (SNP) | VAF 50/108 reads (46%) | catalogued as rs1222587472, COSV99415888; called by muse, mutect2, varscan2
- HNRNPF | c.771C>T p.T257= | Silent (SNP) | VAF 107/143 reads (75%) | catalogued as rs367684898, COSV61561958; called by muse, mutect2, varscan2
- IDE | c.2676T>C p.R892= | Silent (SNP) | VAF 82/334 reads (25%) | catalogued as COSV99793937; called by muse, mutect2, varscan2
- IGDCC3 | c.1455C>T p.V485= | Silent (SNP) | VAF 111/300 reads (37%) | catalogued as COSV100031021; called by muse, mutect2, varscan2
- IGSF10 | c.5277C>T p.S1759= | Silent (SNP) | VAF 46/122 reads (38%) | catalogued as rs200610854; called by muse, mutect2, varscan2
- ITPRID1 | c.2616G>A p.T872= | Silent (SNP) | VAF 45/147 reads (31%) | catalogued as rs868431306, COSV60081896, COSV60084490; called by muse, mutect2, varscan2
- LGALS4 | c.744G>C p.R248= | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as COSV100313201; called by muse, mutect2, varscan2
- LHX2 | c.360G>C p.L120= | Silent (SNP) | VAF 76/264 reads (29%) | catalogued as COSV101010039; called by muse, mutect2, varscan2
- LRRC36 | c.1587C>G p.L529= | Silent (SNP) | VAF 129/510 reads (25%) | catalogued as COSV99338628; called by muse, mutect2, varscan2
- LRRC4 | c.276C>T p.A92= | Silent (SNP) | VAF 51/150 reads (34%) | catalogued as rs1563094808, COSV99974877; called by muse, mutect2, varscan2
- MGAT5B | c.1176C>T p.I392= | Silent (SNP) | VAF 31/52 reads (60%) | catalogued as rs745399922, COSV56929446; called by muse, mutect2, varscan2
- MYBL2 | c.1212C>T p.G404= | Silent (SNP) | VAF 69/169 reads (41%) | catalogued as COSV99406243; called by muse, mutect2, varscan2
- MYOM1 | c.2937A>G p.V979= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs1044384541, COSV99866298; called by muse, mutect2, varscan2
- NCDN | c.423G>C p.G141= | Silent (SNP) | VAF 58/182 reads (32%) | catalogued as COSV100357290; called by muse, mutect2, varscan2
- PARD3 | c.2307T>C p.L769= | Silent (SNP) | VAF 37/184 reads (20%) | catalogued as COSV100400801; called by muse, mutect2, varscan2
- PMS1 | c.2619G>C p.V873= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV100575599; called by muse, mutect2, varscan2
- PNLIP | c.828G>A p.A276= | Silent (SNP) | VAF 78/313 reads (25%) | catalogued as rs540567809, COSV65039574, COSV65041517; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1143C>T p.H381= (on ENST00000352766; = p.H302= on NM_181334.5) | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs368897846, COSV61232439; called by muse, mutect2, varscan2
- RHOB | c.540G>A p.Q180= | Silent (SNP) | VAF 56/122 reads (46%) | catalogued as COSV99695215; called by muse, mutect2, varscan2
- RIN2 | c.2796C>T p.I932= (on ENST00000255006 / NM_001242581.1; = p.I883= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/124 reads (27%) | catalogued as COSV99656935; called by muse, mutect2, varscan2
- RYR1 | c.4239C>T p.D1413= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as rs761036743, COSV100615466; called by muse, mutect2, varscan2
- SLC4A3 | c.678G>A p.S226= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs764787712, COSV99812751; called by muse, mutect2, varscan2
- SORCS1 | c.273G>A p.R91= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV99545513; called by muse, mutect2, varscan2
- TRPC3 | c.1605G>A p.R535= (on ENST00000379645 / NM_001366479.2; = p.R462= on NM_003305.2) | Silent (SNP) | VAF 44/117 reads (38%) | catalogued as rs1312658554, COSV53378702; called by muse, mutect2, varscan2
- TSC22D4 | c.966C>T p.I322= | Silent (SNP) | VAF 37/58 reads (64%) | catalogued as rs750265100, COSV100190249; called by muse, mutect2, varscan2
- TTC4 | c.510C>T p.A170= | Silent (SNP) | VAF 76/192 reads (40%) | catalogued as rs1450089129, COSV64885104; called by muse, mutect2, varscan2
- USP35 | c.2718C>G p.V906= | Silent (SNP) | VAF 55/161 reads (34%) | catalogued as COSV100416429; called by muse, mutect2, varscan2
- VSIG2 | c.57G>C p.L19= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV99423157; called by muse, mutect2, varscan2
- ZNF804A | c.1305A>C p.T435= | Silent (SNP) | VAF 59/232 reads (25%) | catalogued as COSV100167436; called by muse, mutect2, varscan2
- FOLH1B | n.1434G>T | RNA (SNP) | VAF 54/151 reads (36%) | called by muse, mutect2, varscan2
- MARK3 | c.483+1532G>A | Intron (SNP) | VAF 8/9 reads (89%) | catalogued as COSV99358160; called by muse, mutect2, varscan2
- MICAL3 | c.2241+4632C>T | Intron (SNP) | VAF 44/100 reads (44%) | catalogued as rs764389769, COSV99261216; called by muse, mutect2, varscan2
- ZBTB37 | chr1:173864202 T>C | 5'Flank (SNP) | VAF 24/71 reads (34%) | catalogued as rs1366937001; called by muse, mutect2, varscan2
